Somatic mutation profile of tumor specimen TARGET-20-PAERAH-09A (aliquot TARGET-20-PAERAH-09A-01D) from TARGET case TARGET-20-PAERAH, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.4 years (6,366 days).
Specimen TARGET-20-PAERAH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85ea4ee6-2254-4d6f-9bb4-d8d938186575.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAERAH-14A (Bone Marrow Normal), aliquot TARGET-20-PAERAH-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e6aa51a-9ccf-46e4-9e88-b5fb1ccb74fb

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.1849G>T p.V617F | Missense Mutation (SNP) | VAF 105/260 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs77375493, CM123094, COSV67569051, COSV67571909; ClinVar: risk factor / pathogenic / likely pathogenic / not provided / affects; called by muse, varscan2
- CADM2 | c.599C>T p.A200V (on ENST00000407528 / NM_001167674.2; = p.A202V on NM_153184.4) | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs934666245, COSV67371559; called by muse, mutect2, varscan2
- EPHA5 | c.2455T>A p.F819I | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV56643391, COSV56648267; called by muse, mutect2, varscan2
- MOCOS | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs570875336, COSV54341800; called by muse, mutect2, varscan2
- MYEOV | c.532A>C p.S178R | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as COSV58294409; called by muse, mutect2, varscan2
- PCDHA4 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV63542307; called by muse, mutect2, varscan2
- TET2 | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 32/78 reads (41%) | catalogued as rs749121114, COSV54402156; called by muse, mutect2, varscan2
- TET2 | c.3967G>T p.E1323* | Nonsense Mutation (SNP) | VAF 87/208 reads (42%) | catalogued as COSV54413782; called by muse, mutect2, varscan2
- TLE5 | c.560C>G p.T187S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV55592214; called by muse, mutect2, varscan2
- USH2A | c.2959G>T p.D987Y | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV56332241, COSV56377571; called by muse, mutect2, varscan2
- HNRNPK | c.132_147delinsGA p.L45Tfs*17 | Frame Shift Del (DEL) | VAF 63/200 reads (32%) | called by pindel, varscan2*
- CCDC114 | c.189G>C p.R63= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV59556898; called by muse, mutect2, varscan2
- H3C4 | c.210T>C p.R70= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- NSD1 | c.7809C>T p.L2603= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as rs769301382, COSV61777075; called by muse, mutect2, varscan2
